Somatic mutation profile of tumor specimen TCGA-ND-A4WF-01A (aliquot TCGA-ND-A4WF-01A-11D-A28R-08) from TCGA case TCGA-ND-A4WF, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IIIA; Age at diagnosis: 77.7 years (28,398 days).
Specimen TCGA-ND-A4WF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 552bf64a-2a45-44da-8ebd-931f8f73584a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ND-A4WF-10A (Blood Derived Normal), aliquot TCGA-ND-A4WF-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8572372-a2ea-4d54-95e6-0bdb34bd4251

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 51, Silent 15, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>C p.R465P (on ENST00000281708 / NM_001349798.2; = p.R385P on NM_018315.5) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 129/156 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1360C>T p.H454Y (on ENST00000372530 / NM_001198934.2; = p.H411Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.821); catalogued as rs746650514; called by muse, mutect2, varscan2
- ADAMTSL1 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | catalogued as rs751209198; called by muse, mutect2, varscan2
- C12orf42 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs371400301; called by muse, mutect2, varscan2
- CFAP47 | c.4630T>G p.F1544V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57975180; called by muse, mutect2, varscan2
- CNKSR2 | c.2998A>G p.I1000V | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs373711438; called by muse, mutect2, varscan2
- FBN3 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776301980; called by muse, mutect2, varscan2
- FER | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs1295416752; called by muse, mutect2, varscan2
- FLG | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV64237392; called by muse, mutect2, varscan2
- GAA | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 77/120 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772607616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GARNL3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1008332449, COSV59223838; called by muse, mutect2, varscan2
- IFT74 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs545013743; called by muse, mutect2, varscan2
- KRTAP20-2 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | PolyPhen benign (0.35); catalogued as rs775016775, COSV58182540; called by muse, mutect2, varscan2
- LRRIQ4 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 98/119 reads (82%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs764264230; called by muse, mutect2, varscan2
- MEMO1 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.442); catalogued as COSV99703844; called by muse, mutect2, varscan2
- NUDT14 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs368844988, COSV59306102; called by muse, mutect2, varscan2
- SLC5A8 | c.1762G>C p.D588H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.384); catalogued as COSV101610500; called by muse, mutect2, varscan2
- SPANXN3 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV65140130; called by muse, mutect2
- TLR1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV58305270; called by muse, mutect2, varscan2
- TMEM108 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs145373217; called by muse, mutect2, varscan2
- UBL4A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs782395991, COSV54835566; called by muse, mutect2, varscan2
- UTRN | c.2564T>C p.I855T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs958550043; called by muse, mutect2, varscan2
- ZFAT | c.2996G>A p.C999Y | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245309958, COSV64742952; called by muse, mutect2, varscan2
- ZFPM2 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV65872377; called by muse, mutect2, varscan2
- APOBEC1 | c.451C>A p.H151N | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, varscan2
- ARHGEF11 | c.5G>C p.S2T | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CACNA1A | c.872G>T p.W291L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD4 | c.5305A>G p.K1769E (on ENST00000357008 / NM_001363606.2; = p.K1780E on NM_001273.5) | Missense Mutation (SNP) | VAF 106/108 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYSLTR1 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.111); called by muse, mutect2
- DNAH2 | c.5804T>A p.L1935H | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FARSB | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GCSAML | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GLI3 | c.4657A>G p.S1553G | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA3 | c.2596T>C p.F866L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GSTCD | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNQ3 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KLHL4 | c.647T>A p.L216H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- LIPH | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 156/202 reads (77%) | SIFT tolerated (0.6); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRRC37A3 | c.1104G>C p.E368D | Missense Mutation (SNP) | VAF 74/506 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LUM | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAGEC2 | c.309C>G p.C103W | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- NFAT5 | c.1838C>A p.T613K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NSUN3 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR4X1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- SEC23A | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 27/37 reads (73%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC25A28 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THEG | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- TRIM5 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2
- UNC119 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ZFX | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF560 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- B4GALT7 | c.168C>T p.D56= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1309659292, COSV50353363; called by muse, mutect2
- CCL14 | c.213C>T p.G71= (on ENST00000618404 / NM_032963.4; = p.G87= on NM_032962.4) | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs996690462; called by muse, mutect2
- COPB2 | c.2217T>C p.D739= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- DIAPH2 | c.42C>A p.G14= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- GOLGB1 | c.1218C>T p.L406= | Silent (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2
- HEATR1 | c.2448A>G p.E816= | Silent (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- JARID2 | c.1617G>T p.S539= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs375600114, COSV59198887; called by muse, mutect2, varscan2
- MKX | c.600G>A p.A200= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs779331895, COSV65392454; called by muse, mutect2, varscan2
- PPIG | c.2259C>T p.S753= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs1330736213; called by muse, mutect2, varscan2
- PTPRG | c.1386G>A p.A462= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs757781094, COSV55651978; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3969C>G p.T1323= | Silent (SNP) | VAF 214/480 reads (45%) | catalogued as COSV64101452; called by muse, mutect2, varscan2
- UBA7 | c.1830C>T p.H610= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- USP25 | c.2832A>G p.E944= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1390022515; called by muse, mutect2
- WDR19 | c.1638C>T p.D546= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs753505214; called by muse, mutect2, varscan2
- WDR36 | c.720A>G p.L240= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs779584019; called by muse, mutect2, varscan2
